Somatic mutation profile of tumor specimen TCGA-CJ-5680-01A (aliquot TCGA-CJ-5680-01A-11D-1534-10) from TCGA case TCGA-CJ-5680, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 65.1 years (23,778 days).
Specimen TCGA-CJ-5680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70955af9-7d23-4bd1-b008-c21b7f55116d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5680-11A (Solid Tissue Normal), aliquot TCGA-CJ-5680-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93dd2fae-7ef8-43ae-9ca3-dd6ad43db14f

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 3, Splice Site 1, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.8939C>T p.A2980V | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373701095; called by muse, mutect2, varscan2
- ABCG8 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55392360, COSV99700350; called by muse, mutect2, varscan2
- ARL9 | c.475G>T p.E159* (on ENST00000640821 / NM_001363794.2; = p.E17* on NM_206919.2) | Nonsense Mutation (SNP) | VAF 69/227 reads (30%) | catalogued as COSV63991106; called by muse, mutect2, varscan2
- ATP11A | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52105527, COSV52110008; called by muse, mutect2, varscan2
- BAP1 | c.222del p.D74Efs*4 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as COSV56233118; called by mutect2, pindel, varscan2
- CBWD6 | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs746653970; called by muse, varscan2
- CCNT2 | c.2107T>C p.Y703H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.735); catalogued as COSV51472468; called by muse, mutect2, varscan2
- CEP97 | c.1499G>A p.S500N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59123930; called by muse, mutect2, varscan2
- CLTCL1 | c.4600T>A p.Y1534N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54228610; called by muse, mutect2, varscan2
- CSF1R | c.1425G>C p.E475D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.223); catalogued as COSV53833198; called by muse, mutect2, varscan2
- ERGIC2 | c.482A>C p.D161A | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.335); catalogued as COSV64111831, COSV64113654; called by muse, mutect2, varscan2
- GGT5 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs766222794, COSV54069658; called by muse, mutect2, varscan2
- GIMAP2 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56234889; called by muse, mutect2, varscan2
- HERC2 | c.5351G>T p.R1784L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV55305580, COSV55338416; called by muse, mutect2, varscan2
- KIF20B | c.2863C>A p.Q955K (on ENST00000371728 / NM_001284259.2; = p.Q915K on NM_016195.4) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53305629; called by muse, mutect2, varscan2
- LEMD3 | c.1054A>T p.S352C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV57649761; called by muse, mutect2, varscan2
- MAGEB3 | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV64396951; called by muse, mutect2, varscan2
- MCOLN3 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs568979444, COSV62013767; called by muse, mutect2, varscan2
- MME | c.934T>C p.F312L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs748834417, COSV64706919, COSV64709340; called by muse, mutect2, varscan2
- MTFR1L | c.239+1G>T p.X80_splice | Splice Site (SNP) | VAF 28/91 reads (31%) | catalogued as COSV65355746; called by muse, mutect2, varscan2
- MTSS1 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61496408; called by mutect2, varscan2
- MVP | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs200956879, COSV62421885; called by muse, mutect2, varscan2
- OR4C6 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs760669321, COSV58603350; called by muse, mutect2, varscan2
- PAN2 | c.1270C>G p.P424A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV57753506; called by muse, mutect2, varscan2
- PAPPA2 | c.2014C>A p.L672M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62776508; called by muse, mutect2
- PDGFRA | c.2665T>G p.F889V | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957014; called by muse, mutect2, varscan2
- RANBP17 | c.1554G>T p.M518I | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs776461525, COSV66649029; called by muse, varscan2
- RIMBP2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55464345; called by muse, mutect2, varscan2
- SLC39A10 | c.1201A>G p.N401D | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62766958; called by muse, mutect2, varscan2
- SPATA17 | c.1032T>G p.F344L | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV65121091; called by muse, mutect2, varscan2
- SUPV3L1 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV62845101; called by muse, mutect2, varscan2
- TENM4 | c.2091A>C p.L697F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.08); catalogued as COSV53622079; called by muse, mutect2
- ZDHHC13 | c.1103T>G p.F368C | Missense Mutation (SNP) | VAF 126/416 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV101239991; called by muse, mutect2, varscan2
- AFTPH | c.2725_2730delinsC p.D909Hfs*92 (on ENST00000238855 / NM_203437.3; = p.D882Hfs*92 on NM_017657.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by pindel, varscan2*
- VHL | c.536_539del p.D179Afs*22 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- ARID4A | c.2094T>A p.S698= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV62163116; called by muse, mutect2, varscan2
- CPS1 | c.3642C>A p.T1214= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV51807722; called by muse, mutect2, varscan2
- CWC27 | c.1338C>A p.I446= | Silent (SNP) | VAF 42/168 reads (25%) | catalogued as COSV66885380; called by muse, mutect2, varscan2
- DMKN | c.387C>T p.R129= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs200194624, COSV60085828; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1368C>G p.L456= (on ENST00000439118 / NM_001008949.3; = p.L464= on NM_178495.6) | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV63153068; called by muse, mutect2, varscan2
- MED25 | c.1593C>T p.S531= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs774774157, COSV57203934; ClinVar: likely benign; called by muse, mutect2, varscan2
- MPEG1 | c.1488A>T p.S496= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV57089810; called by muse, mutect2, varscan2
- NPY | c.6A>G p.L2= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV54214927; called by muse, varscan2
- PAX6 | c.555G>A p.E185= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV53792903; called by muse, mutect2, varscan2
- RFX5 | c.1152C>A p.I384= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV51838657; called by muse, mutect2, varscan2
- RYR2 | c.414T>C p.S138= | Silent (SNP) | VAF 76/222 reads (34%) | catalogued as COSV63679454; called by muse, mutect2, varscan2
- TYK2 | c.1590G>T p.G530= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV53386406; called by muse, mutect2, varscan2
- CLCA3P | n.640C>T | RNA (SNP) | VAF 38/117 reads (32%) | catalogued as rs751635904; called by muse, mutect2, varscan2
- MTCL1 | c.2968-3162G>C | Intron (SNP) | VAF 15/54 reads (28%) | catalogued as COSV60405285; called by muse, mutect2, varscan2
